Somatic mutation profile of tumor specimen HTMCP-03-06-02101-01C (aliquot HTMCP-03-06-02101-01C-01D-5099) from CGCI case HTMCP-03-06-02101, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G3.
Specimen HTMCP-03-06-02101-01C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a390d59e-abd8-402d-801b-f8340f45cecd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02101-10A (Blood Derived Normal), aliquot HTMCP-03-06-02101-10A-01D-5099; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f6d95210-ddd7-45dc-b35f-67c69b18b909

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPA1 | c.214T>C p.S72P | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.184); called by muse, mutect2
